Somatic mutation profile of tumor specimen TCGA-ET-A39S-01A (aliquot TCGA-ET-A39S-01A-11D-A19J-08) from TCGA case TCGA-ET-A39S, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 27.4 years (10,000 days).
Specimen TCGA-ET-A39S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0a95ff0-ae5c-49e0-ae59-b05f37be7fe3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A39S-10A (Blood Derived Normal), aliquot TCGA-ET-A39S-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f60e363f-1115-48ce-b629-89822b1eb0c7

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DNAH1 | c.61A>G p.S21G | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1367900149, COSV70233628; called by muse, mutect2, varscan2
- MARS2 | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV56572120; called by muse, mutect2, varscan2
- SHPK | c.924A>G p.P308= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs1052139463, COSV56650006; called by muse, mutect2, varscan2
